CGCI case BLGSP-71-19-00130 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/af918a1b-56ac-4ebc-af60-b0823023c185

Demographics
Sex at birth: female; Race: white; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 3.1 years (1,126 days); Year of diagnosis: 2008; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,033 days (8.3 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Ovary; Sites of involvement: Ovary, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Iliac-external; Tumor largest dimension diameter: 1.3 cm.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 2,669 days (7.3 years); Disease response: Tumor Free.
- Days to follow up: 3,033 days (8.3 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (Flow Cytometry): Positive; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD22 (Flow Cytometry): Positive.
- CD3 (IHC): Negative.
- CD79A (Flow Cytometry): Positive.
- Ki67 (Flow Cytometry): Positive; Specialized molecular test: Ki-67 > 90%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Epstein-Barr Virus (ISH): Positive.
- Lactate Dehydrogenase 639 [Blood test normal range upper: 350].

Other clinical attributes
- Day 0: Weight: 14 kg; Height: 100 cm; BMI: 14.

Biospecimens (3 samples)
- Sample BLGSP-71-19-00130-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Ovary; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-19-00130-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00130-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 2,305 days (6.3 years); Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma, NOS; Extranodal site involvement: 1; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 639; Immunophenotypic analysis method: Flow cytometry, not otherwise specified; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD22.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD79a.
